Gene-level copy-number profile of tumor specimen HCM-BROD-0053-C49-06A from HCMI case HCM-BROD-0053-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Epithelioid sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Tumor grade: G2; Age at diagnosis: 16.0 years (5,851 days).
Specimen HCM-BROD-0053-C49-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Pleural Effusion; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6978575b-f96c-4be8-b1c7-0d66b45f6bd3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0053-C49-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/045e1cae-ffe2-4b55-9add-f868ccdd82d2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 119; copy number 2: 57,668; copy number 3: 604; copy number 4: 8; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:38,601,418–38,605,609, 1 gene, copy number 5: ABCD1P2.

Autosomal genes at a single copy (total copy number 1): 119. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
